Somatic mutation profile of cancer-model specimen HCM-CSHL-0584-C19-85M (3D Organoid, passage 6; aliquot HCM-CSHL-0584-C19-85M-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0584-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 58.7 years (21,437 days).
Specimen HCM-CSHL-0584-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d1dab69-1b52-40fe-b30f-980ea9830646.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0584-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0584-C19-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71a16dd8-09cd-41e8-b8d7-534979359c3d

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 22, Nonsense Mutation 9, Frame Shift Del 2, In Frame Del 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 155/498 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs397516265, CM116379; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 456/456 reads (100%) | hotspot (GDC flag); catalogued as rs876658483, COSV52774899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNG2 | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 205/405 reads (51%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as rs1164294842; called by muse, mutect2, varscan2
- CALCR | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as rs763907185, COSV64006591; called by muse, mutect2, varscan2
- CDK12 | c.2651A>G p.Y884C | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200264056; called by muse, mutect2, varscan2
- CLSTN1 | c.2362C>T p.R788W (on ENST00000377298 / NM_001009566.3; = p.R778W on NM_014944.4) | Missense Mutation (SNP) | VAF 159/346 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1270731621, COSV100790796, COSV63650552; called by muse, mutect2, varscan2
- COL22A1 | c.1586A>G p.K529R | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as rs1227955647; called by muse, varscan2
- ENOX1 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 251/414 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs200537425, COSV99816059; called by muse, mutect2, varscan2
- FLRT2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 98/220 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1256512394; called by muse, varscan2
- FOXJ1 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 628/629 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1015321881; called by muse, mutect2, varscan2
- GLB1L2 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 126/409 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV60277497; called by muse, mutect2, varscan2
- HLA-DQB1 | c.207C>A p.Y69* | Nonsense Mutation (SNP) | VAF 180/294 reads (61%) | catalogued as rs767838386; called by muse, mutect2
- ITGA4 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV101223070; called by muse, mutect2
- LRP2 | c.11206C>T p.R3736C | Missense Mutation (SNP) | VAF 109/258 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275575465, COSV55544664; called by muse, mutect2, varscan2
- MAGI1 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 33/607 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs778851077; called by muse, mutect2
- MAP7D1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 432/816 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs761765823; called by muse, mutect2, varscan2
- OR8B12 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747843848, COSV60911636; called by muse, mutect2, varscan2
- PAN3 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 68/186 reads (37%) | catalogued as COSV56700966; called by muse, mutect2, varscan2
- PCDH8 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 304/911 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100131877; called by muse, mutect2, varscan2
- PEX6 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 186/500 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs757254854, COSV55105777; called by muse, mutect2, varscan2
- PIGU | c.525A>G p.I175M | Missense Mutation (SNP) | VAF 56/328 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.179); catalogued as rs1205128943; called by muse, mutect2, varscan2
- PLPPR3 | c.2051C>T p.S684F (on ENST00000520876 / NM_001270366.2; = p.S712F on NM_024888.2) | Missense Mutation (SNP) | VAF 152/484 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV62459749; called by muse, mutect2, varscan2
- RBM10 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 141/142 reads (99%) | catalogued as COSV61308429; called by muse, mutect2, varscan2
- RBM48 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as rs369894722; called by muse, varscan2
- RNF40 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 108/685 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs1180838040; called by muse, mutect2, varscan2
- SCN4A | c.4358C>G p.A1453G | Missense Mutation (SNP) | VAF 215/450 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV71127091; called by muse, mutect2, varscan2
- SELPLG | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 244/531 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as rs145775085; called by muse, mutect2, varscan2
- SLC16A6 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 107/218 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555749415; called by muse, mutect2, varscan2
- STX11 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 304/553 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV62449182, COSV62449325; called by muse, mutect2, varscan2
- SULT1B1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779362138, COSV60206651; called by muse, mutect2, varscan2
- TEPSIN | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 391/391 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as rs779349589, COSV56142254; called by muse, mutect2, varscan2
- TKFC | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 174/540 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as rs144053132; called by muse, mutect2, varscan2
- TTN | c.21396A>C p.Q7132H (on ENST00000591111; = p.Q6205H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/252 reads (44%) | PolyPhen benign (0); catalogued as COSV60190155; called by muse, mutect2, varscan2
- ZAN | c.3540C>A p.Y1180* | Nonsense Mutation (SNP) | VAF 76/389 reads (20%) | catalogued as rs1447501376; called by muse, mutect2, varscan2
- ZNF121 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as COSV104412351; called by muse, mutect2, varscan2
- ACAP1 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 205/446 reads (46%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- AKAP6 | c.3212T>C p.L1071P | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- APC | c.2719_2724del p.G907_S908del | In Frame Del (DEL) | VAF 157/170 reads (92%) | called by mutect2, pindel, varscan2
- ASB15 | c.1711A>T p.R571* | Nonsense Mutation (SNP) | VAF 38/247 reads (15%) | called by muse, mutect2, varscan2
- BPTF | c.3010C>T p.Q1004* | Nonsense Mutation (SNP) | VAF 68/195 reads (35%) | called by muse, mutect2, varscan2
- CEACAM18 | c.1086T>A p.N362K | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNA10 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 120/414 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CLUH | c.2613G>C p.K871N (on ENST00000435359; = p.K910N on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/336 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CTSZ | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 94/3466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CTTNBP2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 57/387 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPHB3 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 503/507 reads (99%) | called by muse, mutect2, varscan2
- FAT3 | c.3205G>T p.D1069Y | Missense Mutation (SNP) | VAF 233/351 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO42 | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 130/268 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- FLG | c.2497G>T p.A833S | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GOLGA6D | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 104/121 reads (86%) | SIFT tolerated (0.32); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GPR83 | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 154/457 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRID2IP | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 188/661 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFT81 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 91/207 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAML | c.312A>T p.Q104H (on ENST00000356289 / NM_001098526.2; = p.Q94H on NM_153206.3) | Missense Mutation (SNP) | VAF 151/506 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK6 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 303/637 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LCORL | c.3541A>C p.N1181H | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- LHFPL6 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 203/542 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- LY75 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 87/178 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- MAGI2 | c.3088C>A p.Q1030K | Missense Mutation (SNP) | VAF 441/552 reads (80%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCKSL1 | c.316A>T p.K106* | Nonsense Mutation (SNP) | VAF 212/434 reads (49%) | called by muse, mutect2, varscan2
- MRPL15 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 144/595 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MTURN | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 124/320 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NECAB2 | c.913_915delinsCTCTGGCGTGAGGAA p.S305delinsLWREE | In Frame Ins (INS) | VAF 88/432 reads (20%) | called by pindel, varscan2*
- OR5C1 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- OXCT1 | c.240_241del p.G81Sfs*14 | Frame Shift Del (DEL) | VAF 106/270 reads (39%) | called by mutect2, pindel, varscan2
- PGA3 | c.101A>C p.E34A | Missense Mutation (SNP) | VAF 32/682 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); called by muse, mutect2
- PKHD1 | c.2918T>C p.V973A | Missense Mutation (SNP) | VAF 305/451 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PTCHD1 | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTGFRN | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 30/798 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.199); called by muse, mutect2
- RPL10 | c.409_415delinsCA p.S137Qfs*12 | Frame Shift Del (DEL) | VAF 37/360 reads (10%) | called by pindel, varscan2*
- SHC3 | c.1374T>G p.D458E | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- SYCP2 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 193/241 reads (80%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOMM34 | c.416A>C p.E139A | Missense Mutation (SNP) | VAF 28/748 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2
- TRIM74 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- ACOT13 | c.240C>T p.P80= | Silent (SNP) | VAF 111/301 reads (37%) | catalogued as rs1187443661; called by muse, mutect2, varscan2
- ADCY8 | c.2388T>C p.N796= | Silent (SNP) | VAF 286/286 reads (100%) | called by muse, varscan2
- ADGRA1 | c.474C>T p.Y158= | Silent (SNP) | VAF 160/378 reads (42%) | catalogued as rs759608334, COSV66926921; called by muse, mutect2
- AHNAK | c.14091C>T p.I4697= | Silent (SNP) | VAF 191/548 reads (35%) | catalogued as rs375130667; called by muse, mutect2, varscan2
- AMFR | c.1869C>T p.T623= | Silent (SNP) | VAF 228/494 reads (46%) | catalogued as COSV51924089; called by muse, mutect2, varscan2
- CNGB3 | c.1515G>A p.T505= | Silent (SNP) | VAF 337/337 reads (100%) | catalogued as rs751667290, COSV60684314; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL1 | c.1101G>A p.T367= | Silent (SNP) | VAF 294/611 reads (48%) | catalogued as rs775371452; called by muse, mutect2, varscan2
- EHD2 | c.1494C>T p.D498= | Silent (SNP) | VAF 221/473 reads (47%) | catalogued as rs570148430, COSV54409637; called by muse, mutect2, varscan2
- IL1R1 | c.1401A>C p.S467= | Silent (SNP) | VAF 130/238 reads (55%) | catalogued as COSV52106020; called by muse, mutect2, varscan2
- KCNA4 | c.492C>T p.G164= | Silent (SNP) | VAF 311/482 reads (65%) | catalogued as rs1342472405, COSV100068461; called by muse, mutect2, varscan2
- KLK4 | c.381C>T p.S127= | Silent (SNP) | VAF 176/374 reads (47%) | catalogued as COSV60676672; called by muse, mutect2, varscan2
- LRFN3 | c.363A>G p.S121= | Silent (SNP) | VAF 501/502 reads (100%) | called by muse, mutect2, varscan2
- MAGEB16 | c.339C>T p.L113= | Silent (SNP) | VAF 10/292 reads (3%) | catalogued as COSV67874587; called by muse, mutect2
- METTL21C | c.189C>T p.Y63= | Silent (SNP) | VAF 91/397 reads (23%) | catalogued as rs140891650; called by muse, mutect2, varscan2
- MRPS21 | c.75C>T p.T25= | Silent (SNP) | VAF 73/192 reads (38%) | catalogued as COSV100481679; called by muse, mutect2, varscan2
- MYO16 | c.4371G>A p.P1457= | Silent (SNP) | VAF 1307/1307 reads (100%) | called by muse, mutect2, varscan2
- PUF60 | c.1512C>T p.G504= (on ENST00000526683 / NM_001362896.2; = p.G487= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 823/823 reads (100%) | catalogued as rs1466383479; called by muse, mutect2, varscan2
- PVALB | c.21G>A p.L7= | Silent (SNP) | VAF 26/556 reads (5%) | catalogued as COSV53411718, COSV53413594; called by muse, mutect2
- SHROOM4 | c.582G>A p.S194= | Silent (SNP) | VAF 265/267 reads (99%) | catalogued as rs370371137; called by muse, mutect2, varscan2
- TXLNA | c.1371G>A p.L457= | Silent (SNP) | VAF 115/249 reads (46%) | catalogued as rs1157453723; called by muse, mutect2, varscan2
- USP29 | c.1131A>G p.L377= | Silent (SNP) | VAF 108/213 reads (51%) | called by muse, mutect2, varscan2
- ZSWIM8 | c.9G>A p.L3= | Silent (SNP) | VAF 138/278 reads (50%) | called by muse, mutect2, varscan2
- JUP | c.*14+104C>T | Intron (SNP) | VAF 393/394 reads (100%) | called by muse, mutect2, varscan2
